Somatic mutation profile of tumor specimen MP2PRT-PARXJS-TMP1-A (aliquot MP2PRT-PARXJS-TMP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PARXJS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,171 days).
Specimen MP2PRT-PARXJS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76ff4804-7923-463e-9995-195f2157c11d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXJS-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXJS-NM1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68a8d722-1340-4098-9a35-ce59e284a82f

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A5 | c.5651C>T p.T1884M (on ENST00000312481; = p.T1880M on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/458 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs553758826, COSV55200198; called by muse, mutect2, varscan2
- EML6 | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 16/577 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1056189867, COSV104423378; called by muse, mutect2
- NFE2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 30/610 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs201284757, COSV56455515; called by muse, mutect2
- LRRC49 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- LRRC66 | c.1018A>G p.K340E | Missense Mutation (SNP) | VAF 238/520 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6C74 | c.349T>C p.S117P | Missense Mutation (SNP) | VAF 263/542 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BTBD9 | c.1686C>T p.S562= | Silent (SNP) | VAF 187/445 reads (42%) | called by muse, mutect2, varscan2
- CACNA1H | c.1362C>A p.G454= | Silent (SNP) | VAF 299/702 reads (43%) | called by muse, mutect2, varscan2
- PPP1R26 | c.1704G>A p.P568= | Silent (SNP) | VAF 38/799 reads (5%) | catalogued as rs143922539; called by muse, mutect2
- XIST | n.11017T>C | RNA (SNP) | VAF 43/226 reads (19%) | called by muse, mutect2, varscan2
